Somatic mutation profile of tumor specimen MMRF_1780_1_BM_CD138pos (aliquot MMRF_1780_1_BM_CD138pos_T1_KBS5U_L06422) from MMRF case MMRF_1780, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 65.4 years (23,893 days).
Specimen MMRF_1780_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b96dff03-1dcf-4464-8b7b-c10f8c041b86.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1780_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1780_1_PB_Whole_C3_KBS5U_L06468; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/18e653e0-fb7f-4944-b79a-038f534c2b41

The open-access MAF lists 115 somatic variants for this specimen: 43 protein-altering or splice-affecting, 16 silent, 56 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, 3'UTR 33, Silent 16, Intron 12, 5'UTR 5, RNA 3, 3'Flank 2, Splice Region 1, 5'Flank 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.247C>T p.H83Y | Missense Mutation (SNP) | VAF 11/27 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs121913385, CM053801, CM056557, COSV58682852, COSV58685578, COSV58690009; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- MAX | c.178C>T p.R60W | Missense Mutation (SNP) | VAF 99/111 reads (89%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM122946, COSV52415839; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 50/104 reads (48%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARHGAP10 | c.799A>G p.T267A | Missense Mutation (SNP) | VAF 54/96 reads (56%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs930913612; called by muse, mutect2, varscan2
- CCDC186 | c.2198G>A p.R733Q | Missense Mutation (SNP) | VAF 54/104 reads (52%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as rs758542467; called by muse, mutect2, varscan2
- ENOX1 | c.1390C>G p.L464V | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV54898009; called by muse, mutect2, varscan2
- IGLV4-69 | c.157A>G p.I53V | Missense Mutation (SNP) | VAF 73/157 reads (46%) | SIFT tolerated (0.5); PolyPhen benign (0.129); catalogued as rs573842917; called by muse, mutect2, varscan2
- ITGA2B | c.2747G>A p.C916Y | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); catalogued as rs1393566865; called by muse, mutect2, varscan2
- LRBA | c.6220C>T p.L2074F | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs745484264, COSV100842009; called by muse, mutect2, varscan2
- MYO1F | c.587G>A p.R196H | Missense Mutation (SNP) | VAF 50/93 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs780739771, COSV57799869; called by muse, mutect2, varscan2
- NPHP1 | c.329+5G>T | Splice Region (SNP) | VAF 38/79 reads (48%) | catalogued as rs767777472; called by muse, mutect2, varscan2
- PAQR9 | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 47/94 reads (50%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.487); catalogued as COSV61417946; called by muse, mutect2, varscan2
- PCDH15 | c.4136C>T p.A1379V | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV57390785; called by muse, mutect2, varscan2
- PHLDB1 | c.3002G>A p.R1001H | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs782158725, COSV61876845; called by muse, mutect2, varscan2
- PRKCQ | c.301G>A p.G101R | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs1269685233, COSV54108962; called by muse, mutect2, varscan2
- SCN1A | c.3017A>G p.D1006G (on ENST00000303395 / NM_001202435.3; = p.D995G on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as CD1311690; called by muse, mutect2, varscan2
- SGIP1 | c.1099C>T p.P367S | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV52769097; called by muse, mutect2
- SMCHD1 | c.3584C>T p.S1195L | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV55251141, COSV55252006; called by muse, mutect2, varscan2
- TAFA5 | c.124G>A p.A42T (on ENST00000402357 / NM_001082967.3; = p.A35T on NM_015381.7) | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.909); catalogued as rs779435720, COSV60975714, COSV60994708; called by muse, mutect2, varscan2
- ANKRD46 | c.469A>C p.S157R | Missense Mutation (SNP) | VAF 89/181 reads (49%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATXN2L | c.1709G>C p.R570P | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- BTG4 | c.133C>T p.H45Y | Missense Mutation (SNP) | VAF 57/120 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CATSPER3 | c.491G>T p.R164L | Missense Mutation (SNP) | VAF 25/35 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CERK | c.1510del p.E504Rfs*47 | Frame Shift Del (DEL) | VAF 4/40 reads (10%) | called by mutect2, pindel
- DUS4L-BCAP29 | c.727C>G p.L243V | Missense Mutation (SNP) | VAF 30/187 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- EPHA4 | c.2365C>T p.R789W | Missense Mutation (SNP) | VAF 23/138 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FRMPD4 | c.2552A>G p.D851G | Missense Mutation (SNP) | VAF 21/21 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HNRNPA3 | c.1026T>A p.N342K | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT tolerated (0.15); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- IGHV2-70D | c.155_157delinsTCG p.G52_M53delinsVV | Missense Mutation (TNP) | VAF 12/73 reads (16%) | called by muse*, pindel, varscan2*
- IGHV2-70D | c.125C>G p.T42S | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.087); called by muse, varscan2
- IGHV2-70D | c.83C>G p.P28R | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- MAN2A1 | c.1153G>A p.G385R | Missense Mutation (SNP) | VAF 78/155 reads (50%) | SIFT tolerated (0.44); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MYO1E | c.3+1G>C p.X1_splice | Splice Site (SNP) | VAF 12/20 reads (60%) | called by muse, mutect2, varscan2
- NELL2 | c.1868A>G p.D623G | Missense Mutation (SNP) | VAF 62/131 reads (47%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- NYNRIN | c.5225C>G p.P1742R | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PTPRD | c.387C>A p.D129E | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- SEC22B | c.472C>A p.Q158K | Missense Mutation (SNP) | VAF 55/124 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SF3B1 | c.3605T>G p.F1202C | Missense Mutation (SNP) | VAF 19/151 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- SLC24A3 | c.1088C>A p.A363D | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT tolerated (0.49); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- TAP1 | c.1634C>A p.T545N | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.131); called by muse, mutect2
- TENM2 | c.5812G>C p.D1938H (on ENST00000518659 / NM_001122679.2; = p.D1699H on NM_001080428.3) | Missense Mutation (SNP) | VAF 32/45 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- TSPAN31 | c.243C>G p.I81M | Missense Mutation (SNP) | VAF 130/281 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- VCAN | c.3155C>G p.T1052R | Missense Mutation (SNP) | VAF 52/113 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- ADD2 | c.645C>T p.I215= | Silent (SNP) | VAF 36/74 reads (49%) | called by muse, varscan2
- CDC5L | c.288C>T p.C96= | Silent (SNP) | VAF 35/80 reads (44%) | catalogued as rs773080124; called by muse, mutect2, varscan2
- DAAM2 | c.1626A>G p.P542= | Silent (SNP) | VAF 59/97 reads (61%) | called by muse, mutect2, varscan2
- DLK1 | c.528C>A p.P176= | Silent (SNP) | VAF 30/236 reads (13%) | called by muse, mutect2, varscan2
- FEZF2 | c.957G>A p.T319= | Silent (SNP) | VAF 36/83 reads (43%) | catalogued as rs1559836026; called by muse, mutect2, varscan2
- FOCAD | c.4056T>C p.P1352= | Silent (SNP) | VAF 64/146 reads (44%) | called by muse, varscan2
- IGDCC3 | c.2301G>A p.A767= | Silent (SNP) | VAF 45/87 reads (52%) | catalogued as rs150667824; called by muse, mutect2, varscan2
- IGHV2-70D | c.303T>G p.L101= | Silent (SNP) | VAF 22/59 reads (37%) | called by muse, varscan2
- ITGB4 | c.2025C>T p.D675= | Silent (SNP) | VAF 35/91 reads (38%) | catalogued as rs202097958; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KRT73 | c.732C>T p.D244= | Silent (SNP) | VAF 17/30 reads (57%) | catalogued as rs773867921; called by muse, mutect2, varscan2
- KRT76 | c.1749C>T p.S583= | Silent (SNP) | VAF 32/63 reads (51%) | catalogued as rs554038954; called by muse, mutect2, varscan2
- KRTAP12-1 | c.48G>A p.A16= | Silent (SNP) | VAF 64/130 reads (49%) | catalogued as rs782395683, COSV59969608; called by muse, mutect2, varscan2
- NR2F1 | c.894C>T p.H298= | Silent (SNP) | VAF 80/157 reads (51%) | called by muse, mutect2, varscan2
- OLFM3 | c.1320C>T p.H440= (on ENST00000338858 / NM_001288821.1; = p.H420= on NM_058170.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 73/153 reads (48%) | catalogued as rs955875700; called by muse, mutect2, varscan2
- SPIRE2 | c.1233G>A p.A411= | Silent (SNP) | VAF 53/99 reads (54%) | catalogued as rs774234787, COSV65556008; called by muse, mutect2, varscan2
- TRIM69 | c.1077G>A p.E359= (on ENST00000329464 / NM_182985.5; = p.E200= on NM_080745.5) | Silent (SNP) | VAF 15/115 reads (13%) | called by muse, mutect2, varscan2
- ADGRL2 | c.-16C>A | 5'UTR (SNP) | VAF 102/222 reads (46%) | catalogued as COSV54666889; called by muse, mutect2, varscan2
- ALDH1L1 | c.*29T>C | 3'UTR (SNP) | VAF 38/85 reads (45%) | called by muse, mutect2, varscan2
- ANKRD12 | c.*534T>C | 3'UTR (SNP) | VAF 39/72 reads (54%) | called by muse, mutect2, varscan2
- APBB2 | c.1042-63del | Intron (DEL) | VAF 4/28 reads (14%) | catalogued as rs375530541; called by pindel, varscan2
- ATP2B4 | c.*922G>A | 3'UTR (SNP) | VAF 29/127 reads (23%) | called by muse, mutect2, varscan2
- C15orf39 | c.*581T>C | 3'UTR (SNP) | VAF 32/80 reads (40%) | called by muse, mutect2, varscan2
- C5orf58 | c.-85+383G>A | Intron (SNP) | VAF 32/71 reads (45%) | called by muse, mutect2, varscan2
- CD2AP | c.*2410C>A | 3'UTR (SNP) | VAF 42/97 reads (43%) | called by muse, mutect2, varscan2
- CNOT3 | c.2037+334G>A | Intron (SNP) | VAF 68/131 reads (52%) | catalogued as rs944624219; called by muse, mutect2, varscan2
- CNOT4 | c.*325A>T | 3'UTR (SNP) | VAF 51/88 reads (58%) | called by muse, mutect2, varscan2
- COX7A1 | c.-6G>C | 5'UTR (SNP) | VAF 31/66 reads (47%) | called by muse, mutect2, varscan2
- CYB5R3 | c.*1574T>A | 3'UTR (SNP) | VAF 18/44 reads (41%) | called by muse, mutect2, varscan2
- DBNL | c.*2874C>A | 3'UTR (SNP) | VAF 42/79 reads (53%) | called by muse, mutect2, varscan2
- DDX55 | c.1165-40A>T | Intron (SNP) | VAF 100/220 reads (45%) | called by muse, varscan2
- DEF8 | c.*21C>T | 3'UTR (SNP) | VAF 19/42 reads (45%) | catalogued as rs747834411; called by muse, mutect2, varscan2
- EFCAB14 | c.1312+9T>G | Intron (SNP) | VAF 31/183 reads (17%) | called by muse, mutect2, varscan2
- FAM204A | chr10:118307246 ins G | 3'Flank (INS) | VAF 22/58 reads (38%) | called by mutect2, pindel*, varscan2
- GASK1A | c.-279G>C | 5'UTR (SNP) | VAF 32/72 reads (44%) | called by muse, mutect2, varscan2
- GLUL | c.*725G>C | 3'UTR (SNP) | VAF 36/133 reads (27%) | called by muse, mutect2, varscan2
- GRHPR | c.493+191C>A | Intron (SNP) | VAF 54/95 reads (57%) | catalogued as rs925796156; called by muse, mutect2, varscan2
- HDAC4 | c.22+54479G>A | Intron (SNP) | VAF 34/84 reads (40%) | called by muse, mutect2, varscan2
- HSPA1A | c.-86G>A | 5'UTR (SNP) | VAF 25/124 reads (20%) | called by muse, mutect2, varscan2
- IMMP2L | c.239+95373C>T | Intron (SNP) | VAF 45/102 reads (44%) | called by muse, mutect2, varscan2
- KIF6 | c.*3114C>G | 3'UTR (SNP) | VAF 8/44 reads (18%) | called by muse, varscan2
- LINC02873 | n.2302C>G | RNA (SNP) | VAF 19/46 reads (41%) | called by muse, mutect2, varscan2
- LINGO1-AS1 | n.40A>G | RNA (SNP) | VAF 7/16 reads (44%) | called by muse, varscan2
- LRP1B | c.*149T>G | 3'UTR (SNP) | VAF 28/52 reads (54%) | called by muse, mutect2, varscan2
- LTB | c.163-141G>A | Intron (SNP) | VAF 96/188 reads (51%) | catalogued as rs4647180; called by muse, mutect2, varscan2
- LTO1 | c.156+148C>G | Intron (SNP) | VAF 38/67 reads (57%) | called by muse, mutect2, varscan2
- MID1IP1 | c.*514A>G | 3'UTR (SNP) | VAF 38/39 reads (97%) | catalogued as rs1341917272; called by muse, mutect2, varscan2
- MOB4 | c.*1414A>G | 3'UTR (SNP) | VAF 58/126 reads (46%) | called by muse, mutect2, varscan2
- NCOA2 | c.*110T>C | 3'UTR (SNP) | VAF 7/112 reads (6%) | called by muse, mutect2
- NFYC-AS1 | n.306G>T | RNA (SNP) | VAF 17/108 reads (16%) | called by muse, mutect2, varscan2
- NREP | c.*793C>T | 3'UTR (SNP) | VAF 9/115 reads (8%) | called by muse, mutect2
- PCDHGA12 | c.*1290G>A | 3'UTR (SNP) | VAF 29/61 reads (48%) | called by muse, mutect2, varscan2
- PCSK1 | c.*2517G>T | 3'UTR (SNP) | VAF 36/72 reads (50%) | called by muse, mutect2, varscan2
- PIK3C3 | c.*321A>G | 3'UTR (SNP) | VAF 4/78 reads (5%) | called by muse, mutect2
- PLPPR4 | c.*207G>A | 3'UTR (SNP) | VAF 39/86 reads (45%) | called by muse, mutect2, varscan2
- PPP2R3A | c.*301T>C | 3'UTR (SNP) | VAF 8/56 reads (14%) | called by muse, mutect2, varscan2
- PTGES3 | chr12:56688354 T>G | 5'Flank (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- RET | c.3187+354G>C | Intron (SNP) | VAF 28/62 reads (45%) | called by muse, mutect2, varscan2
- RNF217 | c.*3741C>G | 3'UTR (SNP) | VAF 15/39 reads (38%) | called by muse, mutect2, varscan2
- SCAF4 | c.*237del | 3'UTR (DEL) | VAF 7/18 reads (39%) | catalogued as COSV54255643; called by mutect2, pindel, varscan2
- SDK2 | c.*435T>A | 3'UTR (SNP) | VAF 16/33 reads (48%) | called by muse, mutect2, varscan2
- SESN3 | c.*1862A>T | 3'UTR (SNP) | VAF 43/104 reads (41%) | called by muse, mutect2, varscan2
- SLC26A7 | c.*2718G>A | 3'UTR (SNP) | VAF 5/96 reads (5%) | catalogued as rs1192114362; called by muse, mutect2
- TACR3 | c.*2993del | 3'UTR (DEL) | VAF 29/79 reads (37%) | called by mutect2, pindel, varscan2
- TBC1D5 | c.*899A>G | 3'UTR (SNP) | VAF 38/81 reads (47%) | called by muse, mutect2, varscan2
- TENM4 | c.*2628G>A | 3'UTR (SNP) | VAF 9/19 reads (47%) | called by muse, mutect2, varscan2
- THAP5 | c.*1540G>A | 3'UTR (SNP) | VAF 29/62 reads (47%) | called by muse, mutect2, varscan2
- TRRAP | chr7:99013273 G>A | 3'Flank (SNP) | VAF 11/23 reads (48%) | catalogued as rs1440312540; called by muse, mutect2, varscan2
- UBQLN1 | c.1249-67A>G | Intron (SNP) | VAF 46/90 reads (51%) | called by muse, mutect2, varscan2
- UGT2B11 | c.*237del | 3'UTR (DEL) | VAF 32/70 reads (46%) | called by mutect2, varscan2
- UGT3A2 | c.-24T>C | 5'UTR (SNP) | VAF 60/123 reads (49%) | called by muse, mutect2, varscan2
- ZNF263 | c.*139C>T | 3'UTR (SNP) | VAF 24/44 reads (55%) | called by muse, mutect2, varscan2
- ZNF844 | c.*3295A>G | 3'UTR (SNP) | VAF 98/222 reads (44%) | catalogued as rs531429218; called by muse, mutect2, varscan2
